Surgical pathology report (de-identified scan), TCGA case TCGA-41-2571, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-2571-01A (Primary Tumor).

(GBM)

SPECIMEN

- A. Right frontal mass
- B. Right frontal mass -
- C. Right frontal mass

CLINICAL NOTES

PRE-OP DIAGNOSIS: Brain tumor.

CLINICAL HISTORY: Brain tumor.

FROZEN SECTION DIAGNOSIS

AFS: Right frontal mass, biopsy - Malignant cells present, defer to final diagnosis on permanent sections.

GROSS DESCRIPTION

A. Received in a container labeled with the patient's name, medical record number and right frontal mass. The specimen consists of fragments of soft tan tissue measuring 0.3 x 0.3 x 0.2 cm. AS-block

B. Container B is labeled with the patient's name, medical record number and "right frontal mass". The specimen consists of soft tan fragments of tissue, measuring 0.5 x 0.4 x 0.3 cm. Quality control slides are obtained from either end of the specimen, the remainder is submitted for tissue procurement.

C. Received in formalin, labeled "right frontal mass" are multiple pink-tan to irregular dusky soft tissue fragments which have an aggregate measurement of 1.2 x 0.7 x 0.3 cm. The specimen is entirely submitted in one cassette. AS-1

MICROSCOPIC DESCRIPTION

Sections of the right frontal mass demonstrate glioblastoma multiforme. There is marked nuclear pleomorphism and mitotic

MICROSCOPIC DESCRIPTION

activity and necrosis. The malignant cells are positive for GFAP and negative for pankeratin.

COMMENT: has reviewed the case and concurs.

14, 3, 20x2

DIAGNOSIS

A. C. Right frontal brain mass, biopsy: Glioblastoma multiforme.

Source: NCI Genomic Data Commons file 0e658388-e5f8-45be-ac9d-62eac386034d (TCGA-41-2571.F3DAFDB9-14E4-4524-AE4D-3D2860532E80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).